Somatic mutation profile of tumor specimen TCGA-EO-A3AU-01A (aliquot TCGA-EO-A3AU-01A-21D-A19Y-09) from TCGA case TCGA-EO-A3AU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 72.3 years (26,406 days).
Specimen TCGA-EO-A3AU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 800e484e-53ea-4bff-93ae-733a80a375c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3AU-10A (Blood Derived Normal), aliquot TCGA-EO-A3AU-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f206f928-78e7-4fa4-94ca-d75a05d830a8

The open-access MAF lists 834 somatic variants for this specimen: 630 protein-altering or splice-affecting, 180 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 388, Silent 180, Frame Shift Del 163, Frame Shift Ins 32, Nonsense Mutation 25, Splice Region 9, Intron 8, In Frame Del 8, 3'Flank 7, Splice Site 5, 5'UTR 3, RNA 3.

Variants (750 of 834; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309del p.D1104Mfs*214 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- APC | c.5978del p.P1993Lfs*51 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs1554087123; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CCND1 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57121499, COSV57122110; called by muse, mutect2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- MED17 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780394, COSV99315614; ClinVar: likely pathogenic; called by muse, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NBN | c.1396dup p.R466Kfs*5 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.1638G>T p.Q546H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1057519940, COSV55883555, COSV55928679, COSV55957396; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 23/72 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SERPINA1 | c.1158del p.E387Rfs*11 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs764325655, CD890162; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCA1 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV101036320; called by muse, mutect2, varscan2
- ABCA2 | c.2801C>G p.A934G (on ENST00000614293; = p.A904G on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV55802318, COSV99686621; called by muse, mutect2, varscan2
- ABCB7 | c.1786C>T p.H596Y (on ENST00000373394 / NM_001271696.3; = p.H597Y on NM_004299.6) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV99503780; called by muse, mutect2, varscan2
- ABCG4 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100266401; called by muse, mutect2, varscan2
- AC109583.1 | c.554A>G p.Q185R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV100167738; called by muse, mutect2, varscan2
- ACACB | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs551468976, COSV58134994; called by mutect2, varscan2
- ACVR2B | c.1505A>T p.N502I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100754137; called by muse, mutect2, varscan2
- ADAMTS15 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.195); catalogued as rs760371321, COSV100142979; called by muse, mutect2, varscan2
- ADAMTS17 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs950899059, COSV99170298; called by muse, mutect2, varscan2
- ADAMTS2 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1252240288, COSV52374485; called by muse, mutect2, varscan2
- ADAT1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.208); catalogued as rs369527792; called by muse, mutect2, varscan2
- ADGRB2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as rs375962742; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs764604854; called by mutect2, pindel, varscan2
- ADRA2A | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99701390; called by muse, mutect2, varscan2
- AFF1 | c.2800G>A p.G934R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as rs775348035, COSV100320119; called by muse, mutect2, varscan2
- AGPAT5 | c.248dup p.N83Kfs*2 | Frame Shift Ins (INS) | VAF 14/23 reads (61%) | catalogued as rs1277762849; called by mutect2, varscan2
- AGPS | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AHDC1 | c.3646G>A p.G1216S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.427); catalogued as rs150667477; called by muse, mutect2, varscan2
- ALDH2 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs756978401, COSV99922620; called by muse, mutect2, varscan2
- ALDH3A2 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99449464; called by muse, mutect2, varscan2
- ALPK3 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99359963; called by muse, mutect2, varscan2
- ANKRD28 | c.2995G>A p.A999T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs751512636, COSV101080171; called by mutect2, varscan2
- ANO1 | c.2102del p.P701Lfs*7 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs1565270546, COSV60286460; called by mutect2, pindel, varscan2
- ANTXR1 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100361540; called by muse, mutect2, varscan2
- ANXA11 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV99626662; called by muse, mutect2, varscan2
- ANXA6 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.679); catalogued as rs371950946, COSV62905535; called by muse, mutect2, varscan2
- AP002748.5 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs747459381, COSV59147332, COSV59149630; called by muse, mutect2, varscan2
- APEH | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99610459; called by muse, mutect2, varscan2
- APTX | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373640152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARAP1 | c.1145C>T p.A382V (on ENST00000393609 / NM_001040118.2; = p.A137V on NM_015242.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.098); catalogued as COSV61989765; called by muse, mutect2, varscan2
- ARAP3 | c.4569G>T p.Q1523H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99499183; called by muse, mutect2, varscan2
- ARHGAP11B | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143705474; called by muse, mutect2, varscan2
- ARHGAP36 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370750175, COSV52271370; called by muse, mutect2, varscan2
- ARID5B | c.2618A>G p.H873R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.878); catalogued as rs1269983870, COSV99688775; called by muse, mutect2, varscan2
- ARL6IP1 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV100435745; called by muse, mutect2, varscan2
- ARVCF | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99258188; called by muse, mutect2, varscan2
- ASAP2 | c.2363C>A p.P788H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99855572; called by muse, mutect2, varscan2
- ASH1L | c.4456C>T p.R1486C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768868132, COSV64210490; called by muse, mutect2, varscan2
- ASMTL | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as COSV101187624; called by muse, mutect2, varscan2
- ATG9B | c.2162del p.P721Qfs*62 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as COSV52486004; called by mutect2, pindel, varscan2
- ATP11C | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100557121; called by muse, mutect2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP4A | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV52866089; called by muse, mutect2, varscan2
- ATP8A2 | c.2833del p.Q945Sfs*36 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as COSV54977608; called by mutect2, pindel, varscan2
- ATRAID | c.449C>G p.T150S (on ENST00000611786; = p.T37S on NM_016085.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV99254209; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs1288664341; called by mutect2, pindel
- BACH1 | c.1667A>T p.D556V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV99727800; called by muse, mutect2, varscan2
- BBX | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360764; called by muse, mutect2, varscan2
- BCL11A | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100184515; called by muse, mutect2, varscan2
- BCL9L | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs760119704, COSV52685994; called by muse, varscan2
- BCOR | c.2555T>C p.F852S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); catalogued as COSV60717015; called by muse, mutect2, varscan2
- BICDL1 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV101287095; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs140917545; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs747341586; called by mutect2, pindel
- BRD4 | c.3811C>T p.Q1271* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV54591222, COSV99649649; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- C14orf28 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV100290010; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- CA1 | c.658A>C p.S220R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99809932; called by muse, mutect2, varscan2
- CACNA1C | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV100214180; called by muse, mutect2, varscan2
- CAPZA3 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99855689; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs762770988, COSV62756627; called by mutect2, varscan2
- CARD14 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs748305221, COSV100413259; called by muse, mutect2, varscan2
- CATSPER1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs370635615; called by muse, mutect2, varscan2
- CAVIN1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV63812126; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC40 | c.3244C>T p.R1082C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1055443134, COSV100162801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC63 | c.1505del p.P502Qfs*34 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as COSV57531644; called by mutect2, pindel, varscan2
- CCDC88B | c.3945G>A p.W1315* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100104843, COSV100105939; called by muse, mutect2, varscan2
- CCNE1 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV99388115; called by muse, mutect2, varscan2
- CCR1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs200932574, COSV99946592; called by muse, mutect2, varscan2
- CD1D | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100939513; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs773511514; called by mutect2, pindel
- CEP164 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99632305; called by muse, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs747064410; called by mutect2, varscan2
- CEP97 | c.584C>A p.T195N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100511482; called by muse, mutect2, varscan2
- CFAP43 | c.3305A>G p.H1102R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs760000742, COSV100828994; called by muse, mutect2, varscan2
- CFAP46 | c.7780C>T p.Q2594* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | catalogued as rs377482174; called by muse, varscan2
- CFAP65 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs144290052; called by muse, mutect2, varscan2
- CGRRF1 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV99370261; called by muse, mutect2, varscan2
- CHAF1B | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023286; called by muse, mutect2, varscan2
- CHD7 | c.8741G>T p.G2914V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101417924, COSV71107698; called by muse, mutect2, varscan2
- CIT | c.3880G>A p.A1294T | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV99947986; called by muse, mutect2, varscan2
- CLCA4 | c.544del p.I182Sfs*56 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs760255767; called by mutect2, varscan2
- CLCN5 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1569540513, COSV100259700; called by muse, mutect2, varscan2
- CLCNKB | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990171; called by muse, mutect2, varscan2
- CLDN6 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1455379665, COSV58511108; called by muse, mutect2, varscan2
- CLUH | c.2101G>A p.A701T (on ENST00000435359; = p.A740T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373602317; called by muse, mutect2, varscan2
- CNTN2 | c.1749del p.K584Sfs*33 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs1244186369, COSV59349146; called by mutect2, pindel, varscan2
- CNTROB | c.2699dup p.V901Sfs*25 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | catalogued as rs35508310; called by mutect2, varscan2
- COL21A1 | c.1893del p.G632Efs*8 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs1319692854; called by mutect2, pindel, varscan2
- COL4A2 | c.4275dup p.G1426Rfs*30 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | catalogued as rs34603892; called by mutect2, varscan2
- COL6A1 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs745485695, COSV62614505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPD | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99852302; called by muse, mutect2
- CPNE2 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1390153672, COSV51963138; called by muse, mutect2, varscan2
- CRYBB3 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308941; called by muse, mutect2, varscan2
- CSF2RA | c.455del p.L152Cfs*35 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs1335772121; called by mutect2, pindel, varscan2
- CST2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100491076; called by muse, mutect2, varscan2
- CTU2 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745514382, COSV56339708; called by muse, mutect2, varscan2
- CXCR6 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56117200; called by muse, mutect2, varscan2
- CXXC1 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs754927781, COSV53273952; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP24A1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.685); catalogued as rs1404238039, COSV99397956; called by muse, mutect2, varscan2
- DAOA | c.59T>C p.L20S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV100298595; called by muse, mutect2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 18/28 reads (64%) | catalogued as COSV99245498; called by mutect2, varscan2
- DCHS1 | c.8623C>T p.R2875W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs201118374; called by muse, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs766714372; called by mutect2, varscan2
- DEAF1 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.164); catalogued as COSV100101626; called by muse, mutect2, varscan2
- DENND11 | c.1179C>G p.F393L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV101530688; called by muse, mutect2, varscan2
- DHX37 | c.981-1G>T p.X327_splice | Splice Site (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100438878; called by muse, mutect2, varscan2
- DICER1 | c.4156G>A p.V1386I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1199615826, COSV100601619; called by muse, mutect2, varscan2
- DISP2 | c.1731del p.L578Wfs*32 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs745509399; called by mutect2, pindel, varscan2
- DKK3 | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100484878; called by muse, mutect2, varscan2
- DMRTB1 | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV101008205; called by muse, mutect2, varscan2
- DMXL1 | c.6583G>A p.A2195T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs1038171077, COSV100222925; called by muse, mutect2, varscan2
- DNAH10 | c.1685G>A p.R562H (on ENST00000409039; = p.R501H on NM_207437.3) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs201031616, COSV68991821; called by muse, mutect2, varscan2
- DNAH5 | c.13119del p.F4374Lfs*3 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as COSV54253577; called by mutect2, pindel, varscan2
- DNAJA3 | c.1188T>G p.I396M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV99276322; called by muse, mutect2
- DOCK6 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs754346655, COSV99624349; called by muse, mutect2, varscan2
- DOCK9 | c.2750C>T p.A917V (on ENST00000376460 / NM_001366676.2; = p.A918V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754407021, COSV100237348; called by muse, mutect2, varscan2
- DST | c.6632C>T p.T2211I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99749420; called by muse, mutect2, varscan2
- DYNC2I2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs201326058, COSV100823131; called by muse, mutect2, varscan2
- EARS2 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV101492136; called by muse, mutect2, varscan2
- ECPAS | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs779772437, COSV99398390; called by muse, mutect2, varscan2
- ECT2L | c.1091del p.N364Ifs*3 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs750438274; called by mutect2, pindel, varscan2
- EDC4 | c.3630-1G>A p.X1210_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | catalogued as rs1358571159, COSV100197382; called by muse, mutect2, varscan2
- EHD4 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.772); catalogued as rs764333028, COSV99587635; called by muse, mutect2, varscan2
- EIF3A | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs764426395, COSV60775185; called by muse, mutect2, varscan2
- EIF4G1 | c.2549A>C p.E850A (on ENST00000346169 / NM_198241.3; = p.E655A on NM_004953.5) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV100071316; called by muse, mutect2, varscan2
- ELP3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1266456486, COSV56461357; called by muse, mutect2, varscan2
- ENKD1 | c.640del p.R214Gfs*14 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs772512087; called by mutect2, pindel, varscan2
- EPHB6 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369872682; called by muse, mutect2, varscan2
- ERCC3 | c.777A>T p.E259D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs772883177, COSV53425973; called by muse, mutect2, varscan2
- ERCC6 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.143); catalogued as COSV100875554; called by muse, mutect2, varscan2
- ERMAP | c.1214dup p.N405Kfs*29 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | catalogued as rs770985563; called by mutect2, pindel, varscan2
- ETV4 | c.399dup p.R134Qfs*49 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | catalogued as rs745944421; called by mutect2, varscan2
- EXOSC9 | c.234dup p.N79* | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs762409826; called by mutect2, varscan2
- FAM111B | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV100639208; called by muse, mutect2, varscan2
- FAM120C | c.2858C>A p.P953H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100069464; called by muse, mutect2, varscan2
- FAM193A | c.2017del p.L673Sfs*142 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as COSV61191975; called by mutect2, pindel, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM3C | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748046331, COSV100739770; called by muse, mutect2, varscan2
- FAM83G | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs374490985; called by muse, mutect2, varscan2
- FBXO27 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.086); catalogued as COSV99494451; called by muse, mutect2, varscan2
- FBXO48 | c.4C>T p.H2Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV58146882; called by muse, mutect2, varscan2
- FCGRT | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs767296631, COSV99675195; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs144178676; called by mutect2, varscan2
- FLG | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV100910286; called by muse, mutect2, varscan2
- FLII | c.2847G>T p.E949D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100374988; called by muse, mutect2, varscan2
- FLOT2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759768535, COSV101204735; called by muse, varscan2
- FLRT3 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425311; called by muse, mutect2, varscan2
- FNBP1 | c.983del p.N328Ifs*7 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | catalogued as rs771301424; called by mutect2, varscan2
- FNDC11 | c.509T>C p.M170T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs202103080, COSV100918729; called by muse, mutect2, varscan2
- FOXC2 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs753504239, CD052464, COSV100234045; called by muse, mutect2, varscan2
- FOXD4L4 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1186269882; called by mutect2, varscan2
- FOXL1 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); catalogued as COSV100206052; called by muse, mutect2, varscan2
- FOXM1 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs753788611, COSV100700776; called by muse, mutect2, varscan2
- FRY | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100968662; called by muse, mutect2, varscan2
- FSTL4 | c.491_493del p.E164del | In Frame Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs763836277; called by pindel, varscan2
- FURIN | c.1613C>A p.S538Y | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.452); catalogued as COSV51575927, COSV99184600; called by muse, mutect2, varscan2
- FZD7 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53811892; called by muse, mutect2, varscan2
- GAPDHS | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs145953617; called by muse, mutect2
- GATAD2B | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs563646987, COSV100897732; called by muse, mutect2, varscan2
- GFRA1 | c.1302del p.K434Nfs*11 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV62604279; called by mutect2, pindel, varscan2
- GJC1 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100395100; called by muse, mutect2, varscan2
- GK2 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100725839, COSV62626962; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GNB2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as rs1461664577, COSV99308561; called by muse, mutect2, varscan2
- GNPDA2 | c.264T>A p.Y88* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99776731; called by muse, mutect2, varscan2
- GPHB5 | c.225dup p.Y76Lfs*3 | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | catalogued as rs1566639983; called by mutect2, pindel, varscan2
- GPR137B | c.117dup p.Y40Lfs*159 | Frame Shift Ins (INS) | VAF 9/21 reads (43%) | catalogued as rs768730454; called by mutect2, pindel, varscan2
- GPR87 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs868831667, COSV53462193; called by muse, mutect2, varscan2
- GPSM1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs782398760, COSV100696539; called by muse, mutect2, varscan2
- GRB10 | c.1537G>A p.V513M (on ENST00000398812; = p.V467M on NM_001001549.3) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1205952141, COSV60007601; called by muse, mutect2, varscan2
- GREB1 | c.4903C>T p.Q1635* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99301974; called by muse, mutect2, varscan2
- HAS3 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780413733, COSV99544068; called by muse, mutect2, varscan2
- HDLBP | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs1225518003, COSV60491846; called by muse, mutect2, varscan2
- HDX | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99946351; called by muse, mutect2, varscan2
- HEATR5B | c.6169G>A p.A2057T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370981258; called by muse, mutect2, varscan2
- HECA | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140780413; called by muse, mutect2, varscan2
- HECTD3 | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99869774; called by muse, mutect2, varscan2
- HIPK4 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775509708, COSV99396228; called by muse, mutect2, varscan2
- HLA-B | c.812T>A p.V271E | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV101317733; called by muse, mutect2, varscan2
- HMCN1 | c.5419G>A p.A1807T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99622283; called by muse, mutect2, varscan2
- HPS3 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as rs1314424927, COSV99937047; called by muse, mutect2, varscan2
- HPS6 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100154752; called by muse, mutect2, varscan2
- HS3ST1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV50023165, COSV99136666; called by muse, mutect2, varscan2
- HSPA2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV55968558; called by muse, mutect2, varscan2
- HSPB3 | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV100115846; called by muse, mutect2
- HTT | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs113106141, COSV100750241; called by muse, mutect2, varscan2
- IFITM5 | c.95del p.P32Rfs*6 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | catalogued as rs774773661; called by mutect2, pindel, varscan2
- IFNAR2 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV99269707; called by muse, mutect2, varscan2
- IGSF8 | c.479del p.P160Qfs*15 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs754902711; called by mutect2, pindel, varscan2
- IL27RA | c.351dup p.V118Rfs*19 | Frame Shift Ins (INS) | VAF 12/43 reads (28%) | catalogued as rs1274155488; called by mutect2, pindel, varscan2
- ILF3 | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs745657850, COSV99139275; called by muse, mutect2, varscan2
- INCENP | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs748167850, COSV53913379, COSV99610548; called by muse, mutect2, varscan2
- INPP5D | c.1834G>A p.A612T (on ENST00000445964 / NM_001017915.3; = p.A611T on NM_005541.5) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as rs754601445, COSV100856426; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS5 | c.2327C>T p.T776I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100399379; called by muse, mutect2, varscan2
- INTS6 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.095); catalogued as rs369926922; called by muse, mutect2, varscan2
- ITGA6 | c.3351del p.K1117Nfs*? (on ENST00000442250; = p.K1078Nfs*48 on NM_001079818.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs201055917; ClinVar: uncertain significance; called by mutect2, varscan2
- ITPKB | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99683497; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV101198119; called by muse, mutect2, varscan2
- JADE1 | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99885113; called by muse, mutect2, varscan2
- JAKMIP3 | c.572A>G p.H191R | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100058448; called by muse, mutect2, varscan2
- KAT2A | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99863302; called by muse, mutect2, varscan2
- KAT6B | c.4316T>C p.V1439A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV99767074; called by muse, mutect2, varscan2
- KCNA6 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99768200; called by muse, mutect2
- KCNA6 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54974128, COSV99768741; called by muse, mutect2, varscan2
- KCNJ13 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99289157; called by muse, mutect2, varscan2
- KCNJ13 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52085696; called by muse, mutect2, varscan2
- KCNK18 | c.302G>T p.W101L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100571955, COSV100572164; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIF15 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as rs149121158; called by muse, mutect2
- KIF1A | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs780483327, COSV100239452; called by muse, mutect2, varscan2
- KLHL12 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV100935608; called by muse, mutect2, varscan2
- KLHL13 | c.136T>C p.S46P | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV99450713; called by muse, mutect2, varscan2
- KLHL34 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1414080345, COSV65278909; called by muse, mutect2, varscan2
- KMT2D | c.15290G>A p.R5097Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.715); catalogued as rs769566680, COSV56481093; called by muse, mutect2, varscan2
- KRT25 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100379748; called by muse, mutect2, varscan2
- LAMC3 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63091062; called by muse, mutect2, varscan2
- LANCL3 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs1186684399, COSV101065407; called by muse, mutect2, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs746633076; called by mutect2, varscan2
- LBP | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.348); catalogued as COSV99460197; called by muse, mutect2
- LEP | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV100451321, COSV58241590; called by muse, mutect2, varscan2
- LMOD3 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs768049475, COSV101341950, COSV70455673; called by muse, varscan2
- LRCH2 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57749961; called by muse, mutect2, varscan2
- LRP1 | c.11567C>T p.T3856M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as rs747715215, COSV54517499; called by muse, mutect2, varscan2
- LRRC59 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs747583013, COSV56813741; called by muse, mutect2
- LRRC8B | c.1175G>A p.S392N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100446384; called by muse, mutect2, varscan2
- LRRC8C | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100967847; called by muse, mutect2, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- MADD | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100210800; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs753121050, COSV99167588; called by muse, mutect2, varscan2
- MAPKAPK3 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100781716; called by muse, mutect2, varscan2
- MBD5 | c.3253G>A p.V1085I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as rs199626531, COSV68695492; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs762648935; called by mutect2, pindel, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs746267361; called by mutect2, varscan2
- MCCC1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99659258; called by muse, mutect2, varscan2
- MCM7 | c.1644del p.S549Pfs*8 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as COSV100384600, COSV57996372; called by mutect2, pindel, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs750092100; called by mutect2, varscan2
- MEA1 | c.405A>G p.P135= | Splice Region (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99775518; called by muse, mutect2, varscan2
- MFGE8 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99183927; called by muse, mutect2, varscan2
- MGRN1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99273629; called by muse, mutect2, varscan2
- MICAL1 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs201978922, COSV57807061; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MKNK1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564635920, COSV100360910; called by muse, mutect2, varscan2
- MMP15 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143912189; called by muse, mutect2, varscan2
- MNX1 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as rs759900602, COSV99429506; called by muse, mutect2, varscan2
- MPDU1 | c.304T>G p.S102A | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV100001902; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3061G>A p.V1021I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as rs752545389, COSV100186366, COSV100187187; called by muse, mutect2, varscan2
- MRGPRX3 | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101283459; called by muse, mutect2, varscan2
- MRPL37 | c.657_659del p.L220del | In Frame Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs751691987; called by mutect2, pindel, varscan2
- MSH5 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs766003915, COSV100994622; called by muse, mutect2, varscan2
- MTA1 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs782149547, COSV100494814; called by muse, mutect2, varscan2
- MYF6 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57352755; called by muse, mutect2, varscan2
- MYH15 | c.4430C>T p.A1477V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs763787418, COSV56323056; called by muse, mutect2, varscan2
- MYO1D | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100553288; called by muse, mutect2, varscan2
- MYO7B | c.5953C>T p.H1985Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as COSV100263960; called by muse, mutect2, varscan2
- MYOM1 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55285857, COSV99864809; called by muse, mutect2, varscan2
- MYRF | c.1874C>T p.A625V (on ENST00000278836 / NM_001127392.3; = p.A616V on NM_013279.4) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs150872059; called by muse, mutect2, varscan2
- NAAA | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99715703; called by muse, mutect2, varscan2
- NANOS3 | c.126+3G>A | Splice Region (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100188398; called by muse, mutect2, varscan2
- NBAS | c.6199G>T p.G2067C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV99866414; called by muse, mutect2, varscan2
- NBEA | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100075659, COSV59826054; called by muse, mutect2, varscan2
- NBEA | c.8369C>T p.A2790V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV100075662; called by muse, mutect2, varscan2
- NCAPD2 | c.1185+2T>C p.X395_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100216729; called by muse, mutect2, varscan2
- NCKAP5 | c.849G>T p.L283F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs774121253, COSV100489336; called by muse, mutect2, varscan2
- NDC80 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV55249978; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs747914168; called by mutect2, varscan2
- NELL1 | c.998-1G>A p.X333_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100117724; called by muse, mutect2, varscan2
- NETO1 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100197994; called by muse, mutect2
- NFATC1 | c.1348del p.A450Pfs*2 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | catalogued as COSV53700386; called by mutect2, pindel, varscan2
- NFE2L1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs780336870, COSV100671295; called by muse, mutect2, varscan2
- NFIB | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as rs1364033144, COSV66627936; called by muse, mutect2, varscan2
- NFKBIA | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750102278, COSV53753912; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NME9 | c.737G>A p.R246Q (on ENST00000333911 / NM_001349024.2; = p.R185Q on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs372956832; called by muse, mutect2, varscan2
- NOC2L | c.2191C>T p.Q731* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100497770; called by muse, mutect2, varscan2
- NOMO1 | c.2174G>A p.G725D | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1335866217, COSV99814115; called by muse, mutect2, varscan2
- NPEPL1 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.828); catalogued as rs778339254, COSV61940269; called by muse, mutect2
- NPHP4 | c.3293C>T p.A1098V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100976648, COSV65399226; called by muse, mutect2, varscan2
- NPPB | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100916053; called by muse, mutect2, varscan2
- NPY1R | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99648373; called by muse, mutect2, varscan2
- NR2C1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs752623779, COSV58008632; called by muse, varscan2
- NR2F2 | c.1237A>C p.I413L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101240894; called by muse, mutect2, varscan2
- NRDC | c.616dup p.T206Nfs*3 | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | catalogued as rs747283256; called by mutect2, varscan2
- NUCB2 | c.915T>C p.V305= | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100082516; called by muse, mutect2, varscan2
- NUP210 | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761847699, COSV99595316; called by muse, mutect2, varscan2
- NUP210L | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs942003406, COSV55141878; called by muse, mutect2
- OBSCN | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs367550916; called by muse, mutect2, varscan2
- OBSCN | c.19726C>T p.H6576Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV100800102; called by muse, mutect2, varscan2
- OBSL1 | c.3091_3093del p.E1031del | In Frame Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs1484655216; called by pindel, varscan2
- OGDHL | c.2084C>A p.P695H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV100934132; called by muse, mutect2, varscan2
- OPRK1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs202146898, COSV55569474, COSV99654512; called by muse, mutect2, varscan2
- OR10A3 | c.686C>A p.P229Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100660197; called by muse, mutect2, varscan2
- OR10X1 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV63767272; called by muse, mutect2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 49/110 reads (45%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1D5 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs371822460; called by muse, mutect2, varscan2
- OR2C3 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201259305, COSV63574876; called by muse, mutect2, varscan2
- OR2T8 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs779344640, COSV60665026; called by muse, mutect2, varscan2
- OR2Y1 | c.415del p.H139Ifs*16 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as COSV57136178; called by pindel, varscan2
- OR3A2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs375263331; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51G2 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV100432004; called by mutect2, varscan2
- OR51I1 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100970215; called by muse, mutect2, varscan2
- OR6B1 | c.175A>C p.M59L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101281624; called by muse, mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs751106039; called by mutect2, varscan2
- OTUD7A | c.1027G>A p.A343T (on ENST00000307050 / NM_001382637.1; = p.A336T on NM_130901.3) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371186560; called by muse, mutect2, varscan2
- OTX1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1458361030, COSV99246086; called by muse, mutect2, varscan2
- PAIP1 | c.721T>A p.L241M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV59087217; called by muse, mutect2, varscan2
- PALB2 | c.3204G>A p.G1068= | Splice Region (SNP) | VAF 8/19 reads (42%) | catalogued as rs786203475, COSV99847867; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAMR1 | c.1814C>T p.A605V (on ENST00000619888 / NM_001001991.3; = p.A622V on NM_015430.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); catalogued as COSV99551977; called by muse, mutect2, varscan2
- PAPOLG | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV99474357; called by muse, mutect2, varscan2
- PCDHA11 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV100246847; called by muse, mutect2, varscan2
- PCDHA13 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99164855; called by muse, mutect2, varscan2
- PCDHA3 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.027); catalogued as rs782054123, COSV100793058; called by muse, mutect2, varscan2
- PCDHB3 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.028); catalogued as rs1419014858, COSV99164074; called by muse, mutect2, varscan2
- PCDHGA2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV99528112; called by muse, mutect2, varscan2
- PCDHGA3 | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99528115; called by muse, mutect2, varscan2
- PCDHGB6 | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1221824873, COSV53988489; called by muse, mutect2, varscan2
- PCGF2 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1186813888; called by muse, mutect2, varscan2
- PCGF3 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs201626789; called by muse, mutect2, varscan2
- PCLO | c.3703C>A p.L1235I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100426128; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs781474699; called by mutect2, varscan2
- PDE4DIP | c.5034G>T p.L1678F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.249); catalogued as COSV57720078; called by muse, mutect2, varscan2
- PDE6B | c.1966G>A p.V656M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV99726778; called by muse, mutect2, varscan2
- PDGFRA | c.1257C>A p.D419E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as COSV99955162; called by muse, mutect2, varscan2
- PDGFRB | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.7); catalogued as COSV99939988; called by muse, mutect2, varscan2
- PDS5B | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as rs780451612, COSV100220307, COSV59731875; called by muse, mutect2, varscan2
- PER3 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs1419241278, COSV100728173; called by muse, mutect2
- PFDN5 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228663; called by muse, mutect2, varscan2
- PGBD1 | c.2411A>G p.N804S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs753147159, COSV52556994; called by muse, mutect2, varscan2
- PHETA1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1025172671, COSV100825287; called by muse, mutect2, varscan2
- PHRF1 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1195199112, COSV52757125; called by muse, mutect2, varscan2
- PIK3R1 | c.1924C>T p.R642* (on ENST00000521381 / NM_181523.3; = p.R372* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs1419325070, COSV57123056; called by muse, mutect2, varscan2
- PIMREG | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as rs748972545, COSV99337757; called by muse, mutect2, varscan2
- PKD1 | c.10295G>A p.S3432N (on ENST00000262304 / NM_001009944.3; = p.S3431N on NM_000296.4) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as COSV99236904; called by muse, mutect2
- PKD1 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs768613812, COSV99236906; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKD1L2 | c.2118G>A p.Q706= | Splice Region (SNP) | VAF 26/66 reads (39%) | catalogued as rs1567660538, COSV100215943; called by muse, mutect2, varscan2
- PLBD1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV53695895; called by muse, mutect2, varscan2
- PLCB2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs767693228, COSV99541343; called by mutect2, varscan2
- PLCB3 | c.3504G>A p.L1168= | Splice Region (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99657025; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as rs953293505; called by mutect2, varscan2
- PMS2 | c.1239del p.D414Tfs*34 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as CD040607; called by mutect2, varscan2
- PMVK | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393953054, COSV100870481; called by muse, mutect2, varscan2
- POLR3E | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs749348251, COSV100241782; called by muse, mutect2, varscan2
- PPP1R1B | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs367543179, COSV99566064; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs540232176; called by mutect2, varscan2
- PPP3R2 | c.130A>G p.M44V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100701308; called by muse, mutect2, varscan2
- PPP6R1 | c.461T>A p.L154Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101336915; called by muse, mutect2, varscan2
- PREX2 | c.1693dup p.S565Ffs*3 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKAR1B | c.260dup p.N88Efs*56 | Frame Shift Ins (INS) | VAF 17/39 reads (44%) | catalogued as rs764069617; called by mutect2, varscan2
- PROSER3 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56552441; called by muse, varscan2
- PRPF38B | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.56); catalogued as COSV100898152; called by muse, mutect2
- PRR5-ARHGAP8 | c.797A>G p.H266R (on ENST00000352766; = p.H143R on NM_181334.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV100423868; called by muse, mutect2, varscan2
- PRRC2B | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765458862, COSV61934603; called by muse, mutect2, varscan2
- PRRC2C | c.753G>A p.M251I (on ENST00000367742; = p.M249I on NM_015172.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100144462; called by muse, mutect2, varscan2
- PRRG3 | c.494del p.G165Afs*7 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as COSV64850606; called by mutect2, pindel, varscan2
- PSD | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs928947276, COSV50042050; called by muse, mutect2, varscan2
- PSEN2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100422708; called by muse, mutect2, varscan2
- PSMD7 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); catalogued as COSV99542512; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTPRS | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99508574; called by muse, mutect2, varscan2
- PTPRU | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV100111218; called by muse, mutect2, varscan2
- PWWP2A | c.989T>C p.V330A | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs760451010, COSV100193597; called by muse, mutect2, varscan2
- RACGAP1 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); catalogued as COSV100407458; called by muse, mutect2, varscan2
- RADIL | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV101271190; called by muse, mutect2
- RAG2 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100270966; called by muse, mutect2, varscan2
- RAI1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99883064; called by muse, mutect2, varscan2
- RASGRP2 | c.1479dup p.R494Afs*54 | Frame Shift Ins (INS) | VAF 14/27 reads (52%) | catalogued as rs774996406; called by mutect2, varscan2
- RAVER2 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886336373, COSV53807274, COSV53810962; called by muse, mutect2, varscan2
- RBM10 | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as COSV100237057; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as rs762006287; called by mutect2, varscan2
- RBPJ | c.252del p.E85Nfs*21 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs761285857; called by mutect2, varscan2
- REXO1 | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV99401899; called by muse, mutect2, varscan2
- RGMB | c.665C>G p.A222G (on ENST00000513185 / NM_001366508.1; = p.A263G on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV100374684; called by muse, mutect2, varscan2
- RIMS2 | c.4682C>A p.P1561H (on ENST00000666250 / NM_001348490.2; = p.P1132H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99153529; called by muse, mutect2
- RMND5B | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759157870, COSV100523151; called by muse, mutect2, varscan2
- RNF25 | c.433_435del p.K145del | In Frame Del (DEL) | VAF 30/119 reads (25%) | catalogued as rs759616909; called by mutect2, pindel, varscan2
- RNF40 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769899565, COSV100221834; called by muse, mutect2, varscan2
- RNH1 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs773018132, COSV100338994; called by muse, mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs757272743; called by mutect2, pindel, varscan2
- RPL10L | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV100022292; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL3 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99335000; called by muse, mutect2, varscan2
- RPS2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.132); catalogued as rs748885661, COSV99238642; called by muse, mutect2, varscan2
- RPUSD3 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100047035; called by muse, mutect2, varscan2
- RUVBL1 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1334752895, COSV100493988; called by muse, mutect2
- RXRB | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs765970270, COSV100553248, COSV59494626; called by muse, mutect2, varscan2
- SACM1L | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.23); catalogued as COSV101203733; called by muse, mutect2, varscan2
- SALL2 | c.2914del p.H972Mfs*11 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV100444489; called by mutect2, pindel, varscan2
- SCAF4 | c.2938C>T p.P980S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV99531944; called by muse, mutect2, varscan2
- SCAP | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.242); catalogued as rs778505510, COSV99650055; called by muse, mutect2, varscan2
- SCNN1G | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as rs775500246, COSV55598002; called by muse, mutect2, varscan2
- SEC14L1 | c.350A>G p.H117R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101170818; called by muse, mutect2
- SEC23IP | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1440497106, COSV100956695; called by muse, mutect2, varscan2
- SELENOW | c.251T>C p.L84S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV101549463; called by muse, mutect2, varscan2
- SEMA5A | c.2965G>A p.V989I | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs376502162; called by muse, mutect2, varscan2
- SERPINA4 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs373176783; called by muse, mutect2, varscan2
- SF3B1 | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100133584, COSV59220238; called by muse, mutect2, varscan2
- SH3KBP1 | c.288C>T p.G96= | Splice Region (SNP) | VAF 16/42 reads (38%) | catalogued as rs746105574, COSV65642809; called by muse, mutect2, varscan2
- SHANK2 | c.4169G>A p.R1390H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs781838189, COSV99571443; called by muse, mutect2, varscan2
- SLC12A7 | c.2563G>T p.G855C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369093; called by muse, mutect2, varscan2
- SLC12A7 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV99369098; called by muse, mutect2, varscan2
- SLC12A8 | c.1998del p.Q667Rfs*17 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as COSV100102119; called by mutect2, pindel, varscan2
- SLC24A2 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747399989, COSV53862090; called by muse, mutect2, varscan2
- SLC25A32 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs554925424, COSV52567585, COSV99884118; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC39A4 | c.575G>A p.S192N (on ENST00000301305 / NM_001374839.1; = p.S167N on NM_017767.3) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV99432849; called by muse, mutect2, varscan2
- SLC44A1 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs372466501; called by muse, mutect2, varscan2
- SLC47A1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs77138970, COSV54498724; called by muse, mutect2, varscan2
- SLC4A11 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs138917586; called by muse, mutect2, varscan2
- SLCO1B3 | c.833dup p.P280Afs*6 | Frame Shift Ins (INS) | VAF 29/104 reads (28%) | catalogued as rs751405974; called by mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 18/29 reads (62%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCC1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs774623334, COSV99592070; called by muse, varscan2
- SNED1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1045964670, COSV60028870; called by muse, mutect2, varscan2
- SNED1 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs919570765, COSV100122007; called by muse, mutect2, varscan2
- SNRNP35 | c.443del p.K148Rfs*6 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs1566105559; called by mutect2, pindel, varscan2
- SNX1 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1167577685, COSV99975780; called by muse, mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SOS1 | c.1132A>T p.T378S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.87); PolyPhen benign (0.045); catalogued as COSV67673689; called by muse, mutect2, varscan2
- SOX1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1287341539, COSV58380581; called by muse, mutect2
- SOX3 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100983640; called by muse, mutect2, varscan2
- SP3 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs753208366, COSV59466046; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATA31A3 | c.3526dup p.S1176Ffs*13 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | catalogued as rs1419655644; called by mutect2, pindel, varscan2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs752907815; called by mutect2, pindel, varscan2
- SPINT2 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100007390; called by muse, mutect2, varscan2
- SPTBN2 | c.2567C>T p.T856I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1243089949, COSV59452189; called by muse, mutect2, varscan2
- SRCAP | c.9460C>T p.R3154W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs755552459, COSV99348898; called by muse, mutect2, varscan2
- STAM | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101092132; called by muse, varscan2
- SVIL | c.2545C>G p.R849G (on ENST00000355867 / NM_021738.3; = p.R423G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100880737; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs570102997; called by mutect2, varscan2
- SYT3 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.369); catalogued as rs769432992, COSV100143738; called by muse, mutect2, varscan2
- TAF15 | c.1589dup p.Y531Lfs*56 (on ENST00000605844 / NM_139215.3; = p.Y528Lfs*56 on NM_003487.4) | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs770087298; called by mutect2, varscan2
- TAOK2 | c.2948del p.G983Vfs*50 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs1370755774; called by mutect2, pindel, varscan2
- TBC1D31 | c.341-1G>A p.X114_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99782205; called by muse, mutect2, varscan2
- TBX6 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99661401; called by muse, mutect2, varscan2
- TEKT4 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs782227280, COSV99726041; called by muse, mutect2, varscan2
- TENT5D | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs137952753, COSV100382518; called by muse, mutect2, varscan2
- THOC6 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99560331; called by muse, mutect2, varscan2
- TIAM2 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100017702; called by mutect2, varscan2
- TJP2 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748523814; called by muse, mutect2, varscan2
- TMC2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as rs771234177, COSV100727247; called by muse, mutect2, varscan2
- TMC4 | c.1939C>A p.L647I (on ENST00000617472 / NM_001145303.3; = p.L641I on NM_144686.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as COSV55827418; called by muse, mutect2
- TMEM132E | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.018); catalogued as COSV100395851; called by muse, mutect2
- TMEM150C | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV101497292; called by muse, mutect2, varscan2
- TMEM59L | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99449852; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM63B | c.2398T>C p.S800P | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV99440824; called by muse, mutect2, varscan2
- TMPRSS11D | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751372363, COSV99384377; called by muse, varscan2
- TMTC4 | c.457G>A p.A153T (on ENST00000376234 / NM_001350577.2; = p.A172T on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs200955718, COSV60892910; called by muse, varscan2
- TNFRSF25 | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV100555823; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNNC1 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51767089; called by muse, mutect2, varscan2
- TNR | c.3682G>A p.V1228M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs778094189, COSV54922603; called by muse, mutect2, varscan2
- TPP2 | c.1982G>T p.R661M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101060124; called by muse, mutect2, varscan2
- TRADD | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV99263358; called by muse, mutect2, varscan2
- TRHR | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV100304591, COSV61232739; called by muse, mutect2, varscan2
- TRIM35 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374227978; called by muse, mutect2, varscan2
- TRPM2 | c.529del p.A177Pfs*6 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs762935066, COSV55967995; called by mutect2, pindel, varscan2
- TTBK1 | c.1316del p.P439Qfs*16 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | catalogued as COSV104389590; called by mutect2, pindel, varscan2
- TTBK2 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376093538, COSV51180623; called by muse, mutect2, varscan2
- TTC21A | c.3442G>A p.G1148S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV99826634; called by muse, mutect2, varscan2
- TUBE1 | c.746del p.K249Sfs*10 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs1554315980; called by mutect2, pindel, varscan2
- UCK2 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs1478901876, COSV100902812, COSV63316864; called by muse, mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs764735138; called by mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs572063854; called by mutect2, varscan2
- UTP20 | c.7951C>A p.L2651I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV99880498; called by muse, mutect2, varscan2
- UXT | c.43del p.E15Rfs*38 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as COSV100243846, COSV100243923; called by mutect2, pindel, varscan2
- VAX2 | c.719dup p.L241Tfs*49 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs782186760; called by mutect2, varscan2
- VCPIP1 | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100125258; called by muse, mutect2, varscan2
- VIL1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs1034186172, COSV99945087; called by muse, mutect2, varscan2
- VSIG2 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763855367, COSV52519270; called by muse, mutect2, varscan2
- WDFY3 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764292766, COSV99881429; called by muse, mutect2, varscan2
- WDR33 | c.2135G>A p.G712D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100459411; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR6 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs781686414, COSV100556088; called by mutect2, varscan2
- WDR70 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs765801273, COSV54284222; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 20/29 reads (69%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIPI1 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100048090; called by muse, mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- WWC3 | c.2972G>A p.R991H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200633994, COSV101080864; called by muse, mutect2, varscan2
- XYLB | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.439); catalogued as COSV99263847; called by muse, mutect2, varscan2
- YTHDF3 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs372046184, COSV72773974; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99648063; called by muse, mutect2, varscan2
- ZDBF2 | c.5624del p.K1875Rfs*39 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs770232797, COSV65623567; called by mutect2, varscan2
- ZFHX4 | c.4193G>A p.R1398H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557590366, COSV51450512, COSV99254327; called by muse, mutect2, varscan2
- ZFYVE26 | c.6190G>T p.G2064W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100719939; called by muse, mutect2, varscan2
- ZGRF1 | c.2895T>A p.F965L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1428248411, COSV100005252; called by muse, mutect2, varscan2
- ZMYM3 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV100077325; called by muse, mutect2
- ZNF142 | c.4774C>T p.R1592W (on ENST00000411696 / NM_001379660.1; = p.R1392W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs760753846, COSV68743219; called by muse, mutect2, varscan2
- ZNF213 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.153); catalogued as rs1222327606, COSV101205913; called by mutect2, varscan2
- ZNF264 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as COSV99567050; called by muse, mutect2, varscan2
- ZNF320 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101206822; called by muse, mutect2, varscan2
- ZNF33A | c.1693T>C p.S565P (on ENST00000458705 / NM_006974.3; = p.S566P on NM_006954.2) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1485770515, COSV100275413; called by muse, mutect2, varscan2
- ZNF385A | c.929C>T p.A310V (on ENST00000338010 / NM_001130967.3; = p.A290V on NM_015481.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs776717174, COSV100566719; called by muse, varscan2
- ZNF418 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.95); PolyPhen benign (0.015); catalogued as rs745584800, COSV101269034, COSV68676030; called by muse, mutect2, varscan2
- ZNF462 | c.4651G>A p.D1551N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257225212, COSV99470479; called by muse, mutect2, varscan2
- ZNF513 | c.981G>T p.E327D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs764482406, COSV99277136; called by muse, mutect2, varscan2
- ZNF524 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99684399; called by muse, mutect2, varscan2
- ZNF532 | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100265818; called by muse, mutect2, varscan2
- ZNF536 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV62818555; called by muse, mutect2, varscan2
- ZNF586 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs557538085, COSV66972344; called by muse, mutect2, varscan2
- ZNF777 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as COSV99924910; called by muse, mutect2, varscan2
- ZNF791 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100588983; called by muse, mutect2, varscan2
- ZNF839 | c.2189G>A p.R730Q (on ENST00000558850 / NM_001267827.1; = p.R846Q on NM_018335.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755669026, COSV99215947; called by muse, mutect2, varscan2
- ZNRD2 | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.173); catalogued as COSV100326047; called by muse, mutect2, varscan2
- ZSCAN20 | c.2773C>A p.H925N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100792455; called by muse, mutect2, varscan2
- ZZEF1 | c.1981T>C p.W661R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV101067343; called by muse, mutect2, varscan2
- ACCSL | c.1469del p.K490Sfs*50 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- AFF3 | c.1354del p.H452Tfs*21 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- AIFM3 | c.112del p.R38Gfs*59 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- AKR1B15 | c.814del p.T272Pfs*6 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- ANK1 | c.1519del p.L507Cfs*26 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2949dup p.S984Ifs*7 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- ARHGAP33 | c.2150del p.P717Lfs*79 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | called by mutect2, pindel, varscan2
- ARID1A | c.1768del p.T590Lfs*29 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- ASPG | c.827dup p.P277Afs*137 | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- ATM | c.5690dup p.R1898Pfs*6 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.1344del p.F448Lfs*9 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- BFAR | c.763del p.Q255Rfs*9 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- C19orf44 | c.409G>C p.G137R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- C3orf35 | n.1369+10del | Splice Region (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- CENPJ | c.830del p.N277Ifs*3 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- CEP104 | c.2269del p.C757Vfs*24 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- CFAP300 | c.333del p.H112Ifs*19 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- CFAP92 | c.874del p.M292Wfs*24 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- CHRNA2 | c.381dup p.G128Wfs*11 | Frame Shift Ins (INS) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- CNN2 | c.600del p.M201Wfs*21 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- CNPPD1 | c.971del p.P324Qfs*89 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- DALRD3 | c.555_556del p.R185Sfs*12 (on ENST00000341949 / NM_001009996.3; = p.R18Sfs*12 on NM_018114.5) | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | called by pindel, varscan2
- DCC | c.2774dup p.N925Kfs*17 | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- DHX58 | c.616del p.Q206Sfs*28 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- DHX9 | c.3193del p.L1065Cfs*20 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- DLG5 | c.5067del p.R1690Gfs*35 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- DNAJB11 | c.94del p.V32Cfs*7 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- DNAJC6 | c.2334del p.A779Qfs*25 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- E2F1 | c.553_554del p.K185Efs*19 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- EXOC5 | c.450del p.F150Lfs*7 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- EZHIP | c.353del p.G118Afs*86 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- FANCD2 | c.3051del p.Q1018Nfs*3 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- FARSA | c.457del p.E153Rfs*7 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- FCGBP | c.5391G>C p.W1797C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- FCGBP | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.155); called by mutect2, varscan2
- FIGNL2 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.237); called by muse, mutect2
- FXR1 | c.1701del p.D568Mfs*2 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- FZD6 | c.410_411del p.F137* | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- GDF2 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GGPS1 | c.735del p.K245Nfs*10 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- GIN1 | c.126dup p.F43Ifs*37 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | called by mutect2, varscan2
- GRIP2 | c.3183del p.G1062Vfs*53 (on ENST00000619221; = p.G965Vfs*53 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- IGF2R | c.5103G>A p.M1701I | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- JAG1 | c.3558del p.N1187Tfs*25 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- JHY | c.587del p.L196* | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- JPT1 | c.434dup p.G146Wfs*32 | Frame Shift Ins (INS) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- KCNMB4 | c.623dup p.F209Vfs*78 | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- KIRREL2 | c.2058del p.T688Lfs*43 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- KMT2B | c.2561_2562del p.E854Afs*34 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2
- LARP1 | c.3087del p.M1030Wfs*13 (on ENST00000518297 / NM_033551.3; = p.M953Wfs*13 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/77 reads (43%) | called by mutect2, pindel, varscan2
- LIFR | c.2267del p.L756* | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- LRCH4 | c.1279del p.A427Pfs*8 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- LUZP1 | c.2810del p.P937Qfs*4 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, varscan2
- MRM1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH1 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTG1 | c.986del p.P329Rfs*28 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- NEMF | c.3154-3del | Splice Region (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- NFXL1 | c.307_309del p.E103del | In Frame Del (DEL) | VAF 19/49 reads (39%) | called by pindel, varscan2
- OCEL1 | c.338_340del p.K113del | In Frame Del (DEL) | VAF 14/40 reads (35%) | called by pindel, varscan2
- PHF12 | c.57dup p.L20Afs*25 | Frame Shift Ins (INS) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.794_795del p.S265* | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by pindel, varscan2
- PIWIL1 | c.1719del p.K573Nfs*19 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- PLA2G7 | c.410dup p.L138Sfs*5 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- PNMT | c.627del p.H210Tfs*20 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- PTEN | c.507_508del p.Q171Efs*8 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- PTOV1 | c.1248del p.*417Sfs*14 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- RAB40C | c.811del p.Q271Rfs*58 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- RBP3 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- ROR2 | c.1083del p.H362Tfs*83 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- RSBN1 | c.1148dup p.L383Ffs*11 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | called by mutect2, varscan2
- RTL9 | c.4099del p.Q1367Kfs*31 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- SDK2 | c.3246del p.S1083Vfs*66 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- SEMA4C | c.1234del p.L412Cfs*3 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- SH3PXD2A | c.328del p.H110Tfs*47 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- SLC22A5 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- SLCO5A1 | c.663del p.Y222Tfs*6 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- STK4 | c.46_47del p.K16Vfs*3 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- STON2 | c.2452del p.A818Qfs*15 (on ENST00000649389 / NM_001366849.2; = p.A761Qfs*15 on NM_001256430.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- TAOK2 | c.2397_2399del p.R800del | In Frame Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- TEC | c.509del p.P170Hfs*5 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- TEX15 | c.7390dup p.S2464Kfs*19 (on ENST00000256246; = p.S2847Kfs*19 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- TIMP2 | c.630del p.K211Sfs*34 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- TMC4 | c.326G>A p.S109N (on ENST00000617472 / NM_001145303.3; = p.S103N on NM_144686.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- TOE1 | c.908_910del p.F303del | In Frame Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- TRPS1 | c.3827del p.N1276Mfs*16 (on ENST00000220888 / NM_001330599.2; = p.N1289Mfs*16 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.378del p.S127Afs*20 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- TUBGCP6 | c.3893del p.P1298Lfs*26 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- USP47 | c.3360del p.G1121Efs*22 (on ENST00000399455 / NM_001372095.1; = p.G1033Efs*22 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/12 reads (58%) | called by mutect2, varscan2
- VANGL1 | c.515del p.F172Sfs*99 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | called by mutect2, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- WNK2 | c.4912del p.D1638Tfs*35 (on ENST00000297954 / NM_001282394.1; = p.D1601Tfs*35 on NM_006648.3) | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- ZC3H3 | c.1122del p.S375Afs*48 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- ZNF106 | c.4182del p.V1396* | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- ZNF2 | c.346del p.S116Qfs*9 (on ENST00000611147 / NM_001291605.2; = p.S103Qfs*9 on NM_021088.4) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- ZNF358 | c.394del p.Q132Rfs*35 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- ZNF592 | c.1333del p.A445Pfs*8 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ACADS | c.456T>C p.F152= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99656572; called by muse, mutect2, varscan2
- ACTRT2 | c.964C>T p.L322= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV101007433; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2784A>G p.T928= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1400192162, COSV99716347; called by muse, mutect2, varscan2
- ADGRB3 | c.594C>T p.C198= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100999474, COSV100999818; called by muse, mutect2, varscan2
- AFAP1L1 | c.108C>T p.A36= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs142671314; called by muse, mutect2, varscan2
- AGAP1 | c.1002G>A p.E334= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100363355; called by muse, mutect2, varscan2
- AOC3 | c.954C>T p.P318= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV99519859; called by muse, mutect2, varscan2
- AP3B2 | c.2301C>T p.S767= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99915906; called by muse, mutect2, varscan2
- APOA5 | c.456C>T p.R152= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99911107; called by muse, mutect2, varscan2
- ARFIP1 | c.927T>C p.N309= (on ENST00000353617 / NM_001287432.1; = p.N277= on NM_014447.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100616960; called by muse, mutect2, varscan2
- ARHGEF2 | c.789G>A p.T263= (on ENST00000361247 / NM_001162383.2; = p.T235= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1287333745, COSV100559857; called by muse, mutect2, varscan2
- ARHGEF7 | c.1713G>A p.E571= (on ENST00000375741 / NM_001113511.2; = p.E393= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs746562060, COSV99520682; called by muse, mutect2, varscan2
- ATP10A | c.1638G>A p.K546= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1485442427, COSV100790714; called by muse, mutect2, varscan2
- ATXN2 | c.3564G>A p.Q1188= (on ENST00000550104; = p.Q1028= on NM_002973.4) | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs1265228125, COSV100373939; called by muse, mutect2, varscan2
- BAG3 | c.402C>A p.S134= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100958166; called by muse, mutect2, varscan2
- BAHCC1 | c.5419C>T p.L1807= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- BCL9L | c.579C>T p.P193= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs758067645, COSV100599380, COSV58305267; called by muse, mutect2, varscan2
- BOC | c.2136C>T p.P712= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs147219655; called by muse, mutect2, varscan2
- BRDT | c.1107C>T p.F369= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1249465244, COSV62863255; called by muse, mutect2, varscan2
- BRPF3 | c.3597C>T p.F1199= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs375841400; called by muse, mutect2, varscan2
- BSN | c.2955C>A p.A985= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99606889; called by mutect2, varscan2
- C12orf50 | c.1068G>A p.T356= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs201866729, COSV53895517, COSV53896910, COSV53897309; called by muse, mutect2, varscan2
- C15orf39 | c.1380G>A p.P460= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1466474079, COSV100641136; called by muse, mutect2, varscan2
- C3orf84 | c.174C>T p.H58= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs1405592129, COSV100234029; called by muse, mutect2, varscan2
- CARD9 | c.102G>A p.L34= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1379397324, COSV100046642; called by muse, mutect2
- CASZ1 | c.2562T>G p.S854= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100680504; called by muse, mutect2, varscan2
- CCER1 | c.51T>C p.G17= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs761676354, COSV62647138; called by muse, mutect2, varscan2
- CCR2 | c.459G>A p.T153= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs145700287, COSV52749789; called by muse, mutect2, varscan2
- CDK12 | c.3918C>A p.S1306= (on ENST00000447079 / NM_016507.4; = p.S1297= on NM_015083.3) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV101420238, COSV70999503; called by muse, mutect2, varscan2
- CEP72 | c.918C>A p.T306= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99374346; called by muse, mutect2, varscan2
- CGN | c.2874C>T p.D958= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs371262483; called by muse, mutect2, varscan2
- CHD1 | c.2584C>T p.L862= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99398923; called by muse, mutect2, varscan2
- CHD8 | c.756A>G p.P252= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101303006; called by muse, mutect2, varscan2
- CHPF2 | c.48C>A p.L16= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99222655; called by muse, mutect2, varscan2
- CLASRP | c.1851C>A p.A617= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99673386; called by muse, mutect2, varscan2
- CLCNKB | c.558G>A p.T186= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs532989748, COSV100990169; called by muse, mutect2, varscan2
- CNTN6 | c.1476C>T p.G492= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100609636; called by muse, mutect2, varscan2
- CNTNAP1 | c.2619C>T p.D873= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as rs1166295273, COSV99225993; called by muse, mutect2
- CNTRL | c.585G>A p.L195= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs767370614, COSV99440671; called by muse, mutect2, varscan2
- COL21A1 | c.2865A>G p.P955= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99776897; called by muse, mutect2
- COX6B1 | c.186G>A p.Q62= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99876771; called by muse, mutect2, varscan2
- CPB2 | c.360T>C p.Y120= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99472867; called by muse, mutect2, varscan2
- CUL4A | c.498G>A p.T166= (on ENST00000375440 / NM_001008895.4; = p.T66= on NM_003589.3) | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1242689634, COSV100416952; called by muse, mutect2, varscan2
- CYP21A2 | c.912C>T p.A304= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs751072381, COSV100925668; called by muse, mutect2, varscan2
- DGCR2 | c.1212C>T p.D404= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs774690663, COSV99593133; called by muse, mutect2, varscan2
- DGKB | c.753C>T p.H251= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99335310; called by muse, mutect2, varscan2
- DIAPH2 | c.1701C>T p.P567= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs371471071, COSV100229935; called by muse, mutect2, varscan2
- DIPK2A | c.1107C>T p.S369= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100237024; called by muse, mutect2, varscan2
- DIRAS1 | c.57C>T p.G19= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100052929; called by muse, mutect2, varscan2
- DISP2 | c.2919G>A p.A973= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs3743141; called by muse, mutect2, varscan2
- DLC1 | c.453G>A p.L151= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99360271; called by muse, mutect2, varscan2
- EHD3 | c.336C>T p.N112= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs146965464; called by muse, mutect2, varscan2
- ENPP2 | c.2196C>T p.N732= (on ENST00000075322 / NM_001040092.3; = p.N784= on NM_006209.5) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs755611358, COSV50015025; called by muse, mutect2, varscan2
- ESPN | c.2043C>T p.I681= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs371653062, COSV64704247; called by muse, mutect2, varscan2
- FAH | c.1026G>A p.P342= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs748360797, COSV99929947; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM234A | c.1266C>T p.S422= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs375362136; called by muse, mutect2, varscan2
- FAM47B | c.744C>T p.R248= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs369604412, COSV61454690; called by muse, mutect2, varscan2
- FANK1 | c.894T>C p.L298= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100902695; called by muse, mutect2, varscan2
- FAT1 | c.1470T>C p.P490= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV101498592; called by muse, mutect2, varscan2
- FBXO6 | c.585G>A p.L195= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99335700; called by muse, mutect2, varscan2
- FNDC3B | c.3438G>A p.A1146= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs572571045, COSV100393325, COSV61039567; called by muse, mutect2, varscan2
- FOXE1 | c.411C>T p.F137= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV64300804; called by muse, mutect2
- FOXJ3 | c.618T>C p.T206= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100691343; called by muse, mutect2, varscan2
- FOXR1 | c.798C>T p.R266= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs782218337, COSV100392760; called by muse, mutect2, varscan2
- FRMPD3 | c.5298G>A p.Q1766= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs1446601775, COSV99345391; called by muse, mutect2, varscan2
- FRMPD4 | c.2820C>T p.H940= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs765472737, COSV101041860; called by muse, mutect2, varscan2
- FYB2 | c.1722G>A p.L574= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100599094; called by muse, mutect2, varscan2
- G6PD | c.924C>T p.Y308= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs782732731, COSV100854910; called by muse, mutect2, varscan2
- GAS6 | c.1890G>A p.P630= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs749169005, COSV100580934, COSV100580945; called by muse, mutect2, varscan2
- GSTZ1 | c.501G>A p.V167= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1185335690, COSV99374309; called by mutect2, varscan2
- GUSB | c.1857G>A p.A619= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs779147312, COSV59220795; called by muse, mutect2, varscan2
- HCRTR1 | c.1041G>A p.V347= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1557579704, COSV101035741; called by muse, mutect2, varscan2
- HECTD1 | c.1092G>A p.R364= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101237284; called by muse, mutect2, varscan2
- HERC2 | c.12597A>G p.V4199= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99869842; called by muse, mutect2, varscan2
- HIP1R | c.1893C>A p.A631= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV53439326, COSV99458045; called by muse, mutect2, varscan2
- HLA-F | c.114C>T p.R38= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99465411; called by muse, mutect2, varscan2
- HTR1E | c.405G>A p.T135= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs371516749, COSV59509271; called by muse, mutect2, varscan2
- IL27RA | c.612G>A p.V204= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs752027122, COSV99651827; called by muse, mutect2, varscan2
- IL3 | c.366C>T p.D122= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99735155; called by muse, mutect2, varscan2
- IRAG1 | c.1785C>A p.T595= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101350822; called by muse, mutect2, varscan2
- IRX4 | c.1320C>T p.D440= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99180750, COSV99181950; called by muse, mutect2, varscan2
- ITPRID1 | c.2580T>C p.C860= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV60085663; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1377G>A p.R459= (on ENST00000439118 / NM_001008949.3; = p.R467= on NM_178495.6) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV63152759; called by muse, mutect2
- KCNQ4 | c.1821G>A p.A607= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs1223475431, COSV100714249; called by muse, mutect2, varscan2
- KRT1 | c.1641C>T p.G547= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs1435882222, COSV52865608; called by muse, mutect2
- KRTAP6-2 | c.18C>T p.Y6= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs375803106, COSV58182435; called by muse, mutect2, varscan2
- LAMA5 | c.6667C>T p.L2223= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99437334; called by muse, mutect2, varscan2
- LTBP3 | c.510G>A p.P170= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1229558573, COSV100098743; ClinVar: likely benign; called by muse, mutect2
- MAFK | c.192C>T p.Y64= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs769419154, COSV99867658; called by muse, mutect2, varscan2
- MAML2 | c.1941G>A p.Q647= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as rs61749250; called by muse, mutect2, varscan2
- MAP4K1 | c.477G>A p.S159= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs373830703; called by muse, mutect2, varscan2
- MAPK8 | c.1182G>A p.S394= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs149971269; called by muse, mutect2, varscan2
- MED13 | c.1773G>A p.Q591= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV101180689; called by muse, mutect2, varscan2
- MED14 | c.2313T>C p.N771= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100247222; called by muse, mutect2, varscan2
- MIP | c.537T>C p.T179= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99234041; called by muse, mutect2, varscan2
- MMP27 | c.576C>T p.D192= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99498144; called by muse, mutect2, varscan2
- MPHOSPH8 | c.228C>T p.Y76= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100824907; called by muse, mutect2, varscan2
- MRPL34 | c.24G>A p.L8= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as COSV99395415; called by muse, mutect2, varscan2
- MRPS17 | c.264T>C p.V88= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV53392091, COSV99567742; called by muse, mutect2, varscan2
- MSX2 | c.432G>A p.K144= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99496722; called by muse, mutect2, varscan2
- MTHFR | c.996G>A p.V332= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100928217; called by muse, mutect2, varscan2
- MYH11 | c.3127C>T p.L1043= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100257258; called by muse, mutect2, varscan2
- MYOM1 | c.3222C>T p.F1074= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs374513799; called by muse, mutect2, varscan2
- MYT1L | c.2712C>A p.P904= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101217914; called by muse, mutect2, varscan2
- NBEAL2 | c.4614C>T p.G1538= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1488826550, COSV52762909; called by muse, mutect2, varscan2
- NDST1 | c.1641G>A p.V547= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs764331441, COSV99938562, COSV99939150; called by muse, mutect2, varscan2
- NELFB | c.1563C>T p.A521= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs774945455, COSV58023686; called by muse, mutect2, varscan2
- NLRP7 | c.618C>T p.Y206= | Silent (SNP) | VAF 4/69 reads (6%) | catalogued as rs202205894, COSV100051385, COSV60175821; called by muse, mutect2
- NOL3 | c.171G>A p.R57= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99220329; called by muse, mutect2
- NPBWR1 | c.945C>T p.R315= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100488067; called by muse, mutect2, varscan2
- NPHP4 | c.3564C>A p.P1188= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs528547815, COSV100976646; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- NUGGC | c.858C>T p.V286= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs772111643, COSV100428710; called by muse, mutect2, varscan2
- OR4X1 | c.630C>T p.F210= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs200969185, COSV100186735, COSV60722430; called by muse, mutect2, varscan2
- OSBP2 | c.2298C>T p.S766= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100212501; called by muse, mutect2, varscan2
- OSCAR | c.315C>T p.C105= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99499771; called by muse, mutect2, varscan2
- PADI4 | c.291C>T p.Y97= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs369225926; called by muse, mutect2, varscan2
- PAX7 | c.519G>A p.A173= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs761556688, COSV100946488; called by muse, mutect2, varscan2
- PCDHB15 | c.2049C>T p.A683= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV51412759, COSV99178849; called by muse, mutect2, varscan2
- PCDHB8 | c.1632C>T p.S544= | Silent (SNP) | VAF 70/419 reads (17%) | catalogued as COSV50808562; called by muse, mutect2, varscan2
- PCDHGA1 | c.18G>A p.K6= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100965917; called by muse, mutect2
84 further variants in this file (0 protein-altering or splice-affecting, 60 silent, 24 other) are not listed here.
